CPTAC case C3L-00365 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0c38f553-6892-4f67-b306-40503b8842b5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Dead; Days to death: 322 days; Year of death: 2017; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 59.3 years (21,654 days); Year of diagnosis: 2016; Days to last known disease status: 322 days; Days to last follow up: 280 days.
   Pathology details: Greatest tumor dimension: 1.2 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 280.

Other clinical attributes
- Weight: 54.1 kg; Height: 162 cm; BMI: 20.61; Comorbidities: Depression.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Cigarettes per day: 20; Tobacco smoking onset year: 1980; Tobacco smoking quit year: 2010; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 30.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00365-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 231 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00365-21: Section location: Left Hemisphere; Percent tumor nuclei: 70; Percent necrosis: 20.
- Sample C3L-00365-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
